Somatic mutation profile of tumor specimen TCGA-04-1369-01A (aliquot TCGA-04-1369-01A-02D-1526-09) from TCGA case TCGA-04-1369, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.6 years (19,571 days).
Specimen TCGA-04-1369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7240f8d-30a6-4b84-8c0f-9053ea25f7da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1369-11A (Solid Tissue Normal), aliquot TCGA-04-1369-11A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f5e52cd-7481-4e75-9826-8fb59cbc413b

The open-access MAF lists 103 somatic variants for this specimen: 82 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 71, Silent 21, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 89/105 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7507T>C p.F2503L (on ENST00000272895 / NM_173076.3; = p.F2185L on NM_015657.3) | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.379); catalogued as COSV55971924; called by muse, mutect2
- ACACB | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs146920013; called by muse, mutect2, varscan2
- ACSL6 | c.1310C>T p.P437L (on ENST00000379240; = p.P462L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57299445; called by muse, mutect2, varscan2
- AHNAK | c.14188C>G p.L4730V | Missense Mutation (SNP) | VAF 62/861 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV99948154; called by muse, mutect2
- ASB10 | c.685G>T p.E229* (on ENST00000420175 / NM_001142459.2; = p.E214* on NM_080871.4) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51999602; called by muse, mutect2, varscan2
- BTN1A1 | c.1466A>G p.Q489R | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55069112; called by muse, mutect2, varscan2
- CALML3 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs537179979, COSV100178835; called by muse, mutect2
- CAPN9 | c.1781A>C p.K594T | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55238275; called by muse, mutect2, varscan2
- CD1A | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745915409, COSV56861711; called by muse, mutect2, varscan2
- CDC42BPA | c.4799G>T p.R1600L (on ENST00000334218 / NM_001366019.2; = p.R1587L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.185); catalogued as COSV62018038; called by muse, mutect2, varscan2
- CDH9 | c.2126A>G p.N709S | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.173); catalogued as COSV50399016; called by muse, mutect2, varscan2
- CDK12 | c.1088C>G p.S363* | Nonsense Mutation (SNP) | VAF 68/81 reads (84%) | catalogued as COSV71002366; called by muse, mutect2, varscan2
- CEP43 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as rs1048698181, COSV100835657; called by muse, mutect2
- CHMP2B | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99773510; called by muse, mutect2
- CNGB3 | c.1319A>G p.Q440R | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60696125; called by muse, mutect2, varscan2
- CNTNAP3 | c.2878G>C p.G960R | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52673455; called by muse, mutect2, varscan2
- COBL | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 28/387 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99473086; called by muse, mutect2
- COL11A1 | c.3853G>A p.G1285S | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62193354; called by muse, mutect2, varscan2
- DHRSX | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 33/338 reads (10%) | catalogued as COSV100585711; called by muse, mutect2, varscan2
- DMRT1 | c.962C>A p.A321E | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV66523653; called by muse, mutect2, varscan2
- FAM47A | c.2092T>A p.W698R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV60499177; called by muse, mutect2, varscan2
- FAM47C | c.1154C>A p.T385N | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV63729464; called by muse, mutect2, varscan2
- FRMD5 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 131/250 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV68724657; called by muse, mutect2, varscan2
- GABRA2 | c.719T>A p.M240K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62918394; called by muse, mutect2, varscan2
- GABRR1 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 26/429 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101033987; called by muse, mutect2
- GLUD2 | c.1560A>C p.Q520H | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as COSV60152852; called by muse, mutect2, varscan2
- GNL1 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV64835480; called by muse, mutect2, varscan2
- GPR25 | c.900C>G p.S300R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58498948; called by muse, varscan2
- H3C6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs367877324, COSV64519825; called by muse, mutect2, varscan2
- HMCN1 | c.14749C>T p.R4917C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777793313, COSV54903401, COSV54909108; called by muse, mutect2, varscan2
- HROB | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs750286909, COSV99809283; called by mutect2, varscan2
- ICAM3 | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV50329780; called by muse, mutect2, varscan2
- IL20 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV65585031; called by muse, mutect2, varscan2
- INVS | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV52447894; called by muse, mutect2, varscan2
- KCNT2 | c.1122-1G>T p.X374_splice | Splice Site (SNP) | VAF 25/211 reads (12%) | catalogued as COSV54071794; called by muse, mutect2, varscan2
- KLHL13 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV53251845; called by muse, mutect2, varscan2
- KRTAP27-1 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV67001542; called by muse, mutect2, varscan2
- LAMP3 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV55616518; called by muse, mutect2, varscan2
- LCE3D | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.764); catalogued as rs1321965561, COSV100909856; called by muse, mutect2
- LMNTD1 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51449836; called by muse, mutect2, varscan2
- LY6G6C | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as rs143912436; called by muse, mutect2, varscan2
- MTA2 | c.694-1G>C p.X232_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV53872005, COSV53874126; called by muse, mutect2, varscan2
- MYH2 | c.925A>C p.N309H | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55446231; called by muse, mutect2, varscan2
- NAALAD2 | c.1555G>C p.G519R | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58964981; called by muse, mutect2, varscan2
- NEDD1 | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV57146041; called by muse, mutect2, varscan2
- NUDT11 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65665435; called by muse, mutect2, varscan2
- OR2G3 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100180641; called by muse, mutect2, varscan2
- OR2G3 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100180643; called by muse, varscan2
- OR9I1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs147846129; called by muse, mutect2, varscan2
- PCDHGC5 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.346); catalogued as COSV52763773; called by muse, mutect2, varscan2
- PDE10A | c.2098-1G>T p.X700_splice | Splice Site (SNP) | VAF 38/145 reads (26%) | catalogued as COSV63103669; called by muse, mutect2, varscan2
- PDE2A | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV57807683; called by muse, mutect2, varscan2
- PGC | c.308A>C p.Y103S | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV63123583; called by muse, mutect2, varscan2
- RAB23 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV58099027; called by muse, mutect2, varscan2
- RCAN3 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); catalogued as rs1007205698, COSV65558074; called by muse, mutect2, varscan2
- RTEL1 | c.3062A>T p.H1021L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1345368614, COSV58899758; called by muse, mutect2, varscan2
- SERPINB7 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as COSV100320892; called by muse, mutect2
- SH3D19 | c.539A>T p.K180M | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV58793096; called by muse, mutect2, varscan2
- SLC13A1 | c.1040A>G p.E347G | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52015681; called by muse, mutect2, varscan2
- SLC3A2 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99061105; called by muse, mutect2
- SLC5A12 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as rs780130101; called by muse, mutect2
- SLC7A4 | c.1883C>A p.A628E | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV100298760; called by muse, mutect2
- SLCO1C1 | c.1337G>C p.G446A | Missense Mutation (SNP) | VAF 106/504 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV56878083; called by muse, mutect2, varscan2
- SPAG4 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65330961; called by muse, mutect2, varscan2
- SS18L1 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.272); catalogued as COSV59212729; called by muse, mutect2, varscan2
- STAG1 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52620831; called by muse, mutect2, varscan2
- STAT3 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as COSV99232895; called by muse, mutect2
- SUGP1 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV99895222; called by muse, mutect2
- SULT1B1 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371978235, COSV60206548, COSV60209064; called by muse, mutect2, varscan2
- SYP | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs782140208, COSV54296635; called by muse, mutect2, varscan2
- TCHHL1 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100916557; called by muse, mutect2
- TONSL | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV68048993, COSV68049127; called by muse, mutect2, varscan2
- TTN | c.6151A>G p.K2051E (on ENST00000591111; = p.K2005E on NM_003319.4) | Missense Mutation (SNP) | VAF 27/132 reads (20%) | PolyPhen possibly damaging (0.894); catalogued as rs1393006247, COSV60272215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYW1 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 18/424 reads (4%) | catalogued as COSV100658829; called by muse, mutect2
- UBQLNL | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs759972716, COSV100974709; called by muse, mutect2
- UGT2B15 | c.471T>G p.C157W | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100592367; called by muse, mutect2, varscan2
- WNK2 | c.4037C>A p.P1346Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52956394; called by muse, varscan2
- ZNF454 | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV60769841; called by muse, mutect2, varscan2
- FEM1B | c.1157_1159del p.L386del | In Frame Del (DEL) | VAF 20/64 reads (31%) | called by pindel, varscan2
- MTSS2 | c.1785del p.T597Rfs*171 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, varscan2
- SUPT5H | c.1018_1027del p.F340Rfs*39 | Frame Shift Del (DEL) | VAF 30/214 reads (14%) | called by mutect2, pindel
- AC126283.2 | c.378A>C p.I126= | Silent (SNP) | VAF 17/287 reads (6%) | catalogued as COSV101144533; called by muse, mutect2
- CCDC178 | c.2571T>C p.T857= (on ENST00000383096 / NM_001105528.3; = p.T819= on NM_198995.3) | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as COSV55791841; called by muse, mutect2, varscan2
- CDH4 | c.585C>T p.S195= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as rs374076466, COSV100848438; called by muse, mutect2, varscan2
- CLSTN3 | c.1917C>T p.D639= | Silent (SNP) | VAF 39/243 reads (16%) | catalogued as rs144078453; called by muse, mutect2, varscan2
- COL27A1 | c.4542G>T p.G1514= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV61928691, COSV61929883; called by muse, mutect2, varscan2
- CTPS2 | c.909G>C p.L303= | Silent (SNP) | VAF 73/286 reads (26%) | catalogued as COSV63723813; called by muse, mutect2, varscan2
- CYP19A1 | c.1053A>G p.Q351= | Silent (SNP) | VAF 93/237 reads (39%) | catalogued as rs1340565699, COSV53061760; called by muse, mutect2, varscan2
- FARP1 | c.2511C>T p.A837= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs139091102; called by muse, mutect2, varscan2
- HRNR | c.414T>C p.D138= | Silent (SNP) | VAF 140/720 reads (19%) | catalogued as COSV64261705; called by muse, mutect2, varscan2
- HYDIN | c.1206C>T p.N402= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs778390461, COSV55496068; called by muse, mutect2, varscan2
- JPH2 | c.972C>T p.H324= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs757316297, COSV65902933, COSV65905706; ClinVar: likely benign; called by muse, mutect2, varscan2
- KMT2C | c.11241C>T p.N3747= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as rs145379616; called by muse, mutect2, varscan2
- LRP6 | c.2613C>A p.G871= | Silent (SNP) | VAF 114/855 reads (13%) | catalogued as COSV53792547; called by muse, mutect2, varscan2
- OR10A3 | c.42C>T p.L14= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs766384859, COSV62460035; called by muse, mutect2, varscan2
- OR8H1 | c.546A>C p.P182= | Silent (SNP) | VAF 41/220 reads (19%) | catalogued as COSV57295503; called by muse, mutect2, varscan2
- REG4 | c.162C>A p.A54= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as COSV56653892, COSV56653918; called by muse, mutect2, varscan2
- SEMA6C | c.1566T>C p.H522= | Silent (SNP) | VAF 67/277 reads (24%) | catalogued as COSV59006622; called by muse, mutect2, varscan2
- SLC47A1 | c.421C>T p.L141= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV54503531; called by muse, mutect2, varscan2
- STAB2 | c.5503C>T p.L1835= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV66344906; called by muse, mutect2, varscan2
- USP13 | c.1263G>A p.Q421= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as COSV55869705; called by muse, mutect2, varscan2
- WNK3 | c.2386C>T p.L796= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV63615485; called by muse, mutect2, varscan2
